RC case RC-B54E — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f7386c3d-997e-4d33-af83-36abd38f817c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1945; Vital status: Dead; Days to death: 155 days; Year of death: 2005; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Anaplastic large cell lymphoma, ALK negative: ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 59.4 years (21,703 days); Year of diagnosis: 2005; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Fever / Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Lymph Node, Hilar / Lymph Node, Mediastinal / Lymph Node, Retroperitoneal / Lymph Node, Supraclavicular / Bone, NOS / Bone marrow / Skin.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 3.7 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP; Days to treatment start: 2 days; Days to treatment end: 44 days; Number of cycles: 4; Treatment outcome: Treatment Stopped Due to Toxicity; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Dexamethasone + Doxorubicin + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: HyperCVAD; Days to treatment start: 101 days; Days to treatment end: 101 days; Number of cycles: 1; Treatment outcome: Progressive Disease; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 101 days; Days to treatment end: 101 days; Number of cycles: 1; Treatment outcome: Progressive Disease; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Cytarabine + Etoposide + Methylprednisolone; Initial disease status: Initial Diagnosis; Regimen or line of therapy: ESHAP; Days to treatment start: 135 days; Days to treatment end: 135 days; Number of cycles: 1; Treatment outcome: Progressive Disease; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Day 153 (end of treatment course 1): Disease response: With Tumor; Imaging type: PET; Imaging result: Positive.

Molecular and laboratory tests
- Lactate Dehydrogenase 851 U/L [Blood test normal range upper: 618].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 77.7 kg; Height: 180 cm; BMI: 24.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 5; Tobacco smoking quit year: 1967.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B54E-NM1-A: Tissue type: Normal; Specimen type: Bone Marrow Components NOS; Preservation method: Frozen.
- Sample RC-B54E-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B54E-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
